Somatic mutation profile of tumor specimen ALCH-B6F0-TTP1-A (aliquot ALCH-B6F0-TTP1-A-1-0-D-A92E-47) from ALCHEMIST case ALCH-B6F0, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 81.3 years (29,697 days).
Specimen ALCH-B6F0-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3f415413-f0d8-4d6d-9ed8-b6131f5b54c4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B6F0-NB1-A (Blood Derived Normal), aliquot ALCH-B6F0-NB1-A-1-0-D-A92E-47; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/938a59d1-e7d8-45af-86cf-a9d79c5d6535

The open-access MAF lists 47 somatic variants for this specimen: 33 protein-altering or splice-affecting, 10 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 24, Silent 10, Intron 3, Frame Shift Del 3, Nonsense Mutation 3, Frame Shift Ins 2, 5'UTR 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- RB1 | c.305_306del p.C102Yfs*7 | Frame Shift Del (DEL) | VAF 12/50 reads (24%) | catalogued as rs587778825; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- TP53 | c.991C>T p.Q331* | Nonsense Mutation (SNP) | VAF 5/44 reads (11%) | hotspot (GDC flag); catalogued as CM1511153, COSV52664188; called by muse, mutect2, varscan2
- TP53 | c.377A>G p.Y126C | Missense Mutation (SNP) | VAF 14/59 reads (24%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1555526335, CM115636, COSV52689293, COSV52760406, COSV52970718; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- ADGRG4 | c.904dup p.I302Nfs*8 | Frame Shift Ins (INS) | VAF 39/258 reads (15%) | catalogued as rs747213187; called by mutect2, pindel, varscan2
- EPHA7 | c.2251G>A p.D751N | Missense Mutation (SNP) | VAF 13/200 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.292); catalogued as COSV65178490; called by muse, mutect2
- FSIP2 | c.1610G>C p.R537T | Missense Mutation (SNP) | VAF 13/106 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1431392704; called by muse, mutect2, varscan2
- KDM4D | c.694C>T p.P232S | Missense Mutation (SNP) | VAF 44/180 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV58634333; called by muse, mutect2, varscan2
- MAPKBP1 | c.401A>T p.K134M | Missense Mutation (SNP) | VAF 22/111 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.89); catalogued as rs779521836; called by muse, mutect2, varscan2
- OTUD3 | c.1087C>T p.R363C | Missense Mutation (SNP) | VAF 29/136 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.539); catalogued as rs1230382652, COSV100908998; called by muse, mutect2, varscan2
- RARA | c.1219C>G p.P407A | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.484); catalogued as COSV54196290; called by muse, mutect2, varscan2
- RTL9 | c.2668C>T p.R890* | Nonsense Mutation (SNP) | VAF 73/217 reads (34%) | catalogued as rs1031379926; called by muse, mutect2, varscan2
- SDR9C7 | c.703G>A p.G235R | Missense Mutation (SNP) | VAF 24/97 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as rs369602151; called by muse, mutect2, varscan2
- SIN3A | c.1361A>T p.D454V | Missense Mutation (SNP) | VAF 21/94 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.091); catalogued as rs150154272; called by muse, mutect2, varscan2
- SPTA1 | c.889G>C p.V297L | Missense Mutation (SNP) | VAF 18/171 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0.062); catalogued as COSV63759810; called by muse, mutect2, varscan2
- ZNF485 | c.776G>A p.R259H | Missense Mutation (SNP) | VAF 17/120 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0.028); catalogued as rs771386204, COSV100700173; called by muse, mutect2, varscan2
- BRPF1 | c.3002C>T p.S1001F | Missense Mutation (SNP) | VAF 9/79 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.795); called by mutect2, varscan2
- CNGA3 | c.1083G>T p.L361F | Missense Mutation (SNP) | VAF 31/141 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- CRYBG3 | c.3988G>A p.D1330N | Missense Mutation (SNP) | VAF 44/165 reads (27%) | SIFT tolerated (0.52); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- CTAGE6 | c.737T>C p.I246T | Missense Mutation (SNP) | VAF 60/352 reads (17%) | SIFT tolerated (0.57); PolyPhen benign (0.287); called by muse, mutect2, varscan2
- CYBC1 | c.373A>G p.M125V | Missense Mutation (SNP) | VAF 21/81 reads (26%) | SIFT tolerated (0.62); PolyPhen benign (0); called by muse, mutect2, varscan2
- DNAH17 | c.12390del p.N4131Tfs*34 | Frame Shift Del (DEL) | VAF 4/42 reads (10%) | called by pindel, varscan2
- KCNH2 | c.3137A>C p.Q1046P | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- LNPEP | c.1001A>G p.K334R | Missense Mutation (SNP) | VAF 35/102 reads (34%) | SIFT tolerated (0.44); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- MALRD1 | c.665C>G p.S222C | Missense Mutation (SNP) | VAF 24/79 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- MAP3K19 | c.2521G>T p.E841* | Nonsense Mutation (SNP) | VAF 20/97 reads (21%) | called by muse, mutect2, varscan2
- NCDN | c.2179T>A p.S727T | Missense Mutation (SNP) | VAF 3/23 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.026); called by muse, varscan2
- PAPOLG | c.1558_1576delinsGT p.Q520Vfs*3 | Frame Shift Del (DEL) | VAF 36/138 reads (26%) | called by pindel, varscan2*
- RP1 | c.2167G>A p.D723N | Missense Mutation (SNP) | VAF 6/92 reads (7%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.994); called by muse, mutect2
- SRSF6 | c.211C>T p.R71W | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.585); called by mutect2, varscan2
- SSR4 | c.445A>G p.T149A | Missense Mutation (SNP) | VAF 17/126 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.832); called by muse, mutect2, varscan2
- THAP1 | c.592T>C p.Y198H | Missense Mutation (SNP) | VAF 27/111 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.478); called by muse, mutect2, varscan2
- TRIM49C | c.501_507+3del p.X167_splice | Splice Site (DEL) | VAF 9/51 reads (18%) | called by mutect2, pindel, varscan2
- WFDC10B | c.17dup p.L7Afs*19 | Frame Shift Ins (INS) | VAF 28/78 reads (36%) | called by mutect2, pindel, varscan2
- APC | c.7977G>A p.V2659= | Silent (SNP) | VAF 10/188 reads (5%) | catalogued as rs1392424178; ClinVar: likely benign; called by muse, mutect2
- DMXL1 | c.4107C>T p.R1369= | Silent (SNP) | VAF 57/194 reads (29%) | called by muse, mutect2, varscan2
- H2BC11 | c.99C>T p.S33= | Silent (SNP) | VAF 57/216 reads (26%) | called by muse, mutect2, varscan2
- KCNC2 | c.426C>T p.G142= | Silent (SNP) | VAF 11/142 reads (8%) | called by muse, mutect2
- POLH | c.789G>A p.G263= | Silent (SNP) | VAF 25/91 reads (27%) | called by muse, mutect2, varscan2
- POLN | c.2337C>T p.A779= | Silent (SNP) | VAF 18/120 reads (15%) | called by muse, varscan2
- RICTOR | c.1317T>G p.P439= | Silent (SNP) | VAF 37/115 reads (32%) | called by muse, mutect2, varscan2
- RYR1 | c.11697G>A p.Q3899= | Silent (SNP) | VAF 13/64 reads (20%) | called by muse, mutect2, varscan2
- TEKT4 | c.534G>A p.L178= | Silent (SNP) | VAF 6/68 reads (9%) | catalogued as COSV54622802; called by mutect2, varscan2
- ZNF835 | c.1062C>T p.R354= | Silent (SNP) | VAF 30/97 reads (31%) | called by muse, mutect2, varscan2
- AC013717.1 | c.1134+25744G>A | Intron (SNP) | VAF 6/83 reads (7%) | called by muse, mutect2
- CNGB1 | c.874+1974G>A | Intron (SNP) | VAF 23/100 reads (23%) | called by muse, mutect2, varscan2
- LYN | c.-264C>G | 5'UTR (SNP) | VAF 16/50 reads (32%) | called by muse, mutect2, varscan2
- PTPRQ | c.181-357G>A | Intron (SNP) | VAF 18/81 reads (22%) | called by muse, mutect2, varscan2
